Somatic mutation profile of tumor specimen TCGA-HT-A61C-01A (aliquot TCGA-HT-A61C-01A-11D-A29Q-08) from TCGA case TCGA-HT-A61C, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 66.5 years (24,276 days).
Specimen TCGA-HT-A61C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b625a9-8477-4909-91f6-733887ed5923.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A61C-10A (Blood Derived Normal), aliquot TCGA-HT-A61C-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73061008-c053-44ea-be8f-4a25d623c274

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 41/169 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MET | c.3028+2T>A p.X1010_splice | Splice Site (SNP) | VAF 30/966 reads (3%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2
- ANXA6 | c.1687T>C p.F563L | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100636919; called by muse, mutect2, varscan2
- ASPH | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1273029835, COSV100727579; called by muse, mutect2
- CAPZA3 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV99856369; called by muse, mutect2, varscan2
- CHD8 | c.1733G>A p.R578H (on ENST00000646647 / NM_001170629.2; = p.R299H on NM_020920.4) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452630110, COSV67869962; called by muse, mutect2, varscan2
- COL27A1 | c.2886G>C p.Q962H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100621012; called by muse, mutect2, varscan2
- CR2 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV100889641; called by muse, mutect2, varscan2
- FSCN3 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV99757148; called by muse, mutect2, varscan2
- HEATR5B | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as rs369632588; called by muse, mutect2, varscan2
- IGFN1 | c.2317G>A p.A773T (on ENST00000295591 / NM_001367841.1; = p.A3230T on NM_001164586.2) | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as rs146376343; called by muse, mutect2, varscan2
- KCND2 | c.1314C>G p.S438R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.242); catalogued as COSV100475868, COSV100477009; called by muse, mutect2, varscan2
- KCNMB2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs553808917, COSV100843943; called by muse, mutect2, varscan2
- LILRA6 | c.1345A>G p.I449V | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99557738; called by muse, mutect2, varscan2
- MET | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 470/1558 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV100577221, COSV59265067; called by muse, varscan2
- MUC16 | c.10913T>C p.I3638T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV101199976; called by muse, mutect2, varscan2
- MYH11 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs768807804, COSV55543701; called by muse, mutect2, varscan2
- MYH2 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs151164070; called by muse, mutect2, varscan2
- MYO7B | c.4262G>A p.R1421H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs372450782; called by muse, mutect2, varscan2
- NAA20 | c.25T>A p.C9S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV100131646; called by muse, mutect2, varscan2
- NAB1 | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.965); catalogued as rs1292397256, COSV100493008; called by muse, mutect2, varscan2
- OPRPN | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777093106, COSV101271071; called by muse, mutect2, varscan2
- OR8K1 | c.20A>T p.H7L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99687314; called by muse, mutect2, varscan2
- PARM1 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV100268099; called by muse, mutect2
- PCSK6 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs775864801, COSV100083551; called by muse, mutect2, varscan2
- RYR3 | c.14138C>T p.T4713M (on ENST00000389232; = p.T4714M on NM_001036.6) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101211892; called by muse, mutect2, varscan2
- SLC15A4 | c.1553T>A p.M518K | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99903595; called by muse, mutect2, varscan2
- SPRED2 | c.803A>C p.Y268S | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.677); catalogued as COSV100710223; called by muse, mutect2, varscan2
- TMEM184C | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99669641; called by muse, mutect2, varscan2
- TRAM1L1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV60291963, COSV60293508; called by muse, mutect2, varscan2
- TRANK1 | c.5831A>G p.Q1944R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV100082974; called by muse, mutect2, varscan2
- TTN | c.49609C>T p.R16537C (on ENST00000591111; = p.R9113C on NM_003319.4) | Missense Mutation (SNP) | VAF 47/127 reads (37%) | PolyPhen benign (0.007); catalogued as rs554701601, COSV60074495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B11 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs113129893, COSV101485253; called by muse, mutect2
- EXOC8 | c.641_643del p.V214del | In Frame Del (DEL) | VAF 37/106 reads (35%) | called by pindel, varscan2
- RFC1 | c.666_668del p.D222del | In Frame Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- SLIT2 | c.1297_1300del p.I433Vfs*8 | Frame Shift Del (DEL) | VAF 59/162 reads (36%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.3483C>G p.P1161= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99178788; called by muse, mutect2, varscan2
- EIF5 | c.135G>A p.A45= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs777278770, COSV99384836; called by muse, mutect2, varscan2
- GFRA2 | c.570G>A p.S190= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs536103646, COSV60777650, COSV60779573; called by muse, mutect2, varscan2
- OR56A4 | c.738C>T p.D246= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1259505196, COSV100417565; called by muse, mutect2, varscan2
- PGM2L1 | c.270G>A p.Q90= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99994878; called by muse, mutect2, varscan2
- POTED | c.246T>A p.T82= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as COSV100203134; called by muse, mutect2, varscan2
- TMEM67 | c.2922C>T p.I974= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV60044405; called by muse, mutect2, varscan2
- TRAF2 | c.1050C>T p.Y350= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs777906246, COSV99916496; called by muse, mutect2, varscan2
- TCF7 | c.1027-235G>T | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- VN1R10P | n.837G>A | RNA (SNP) | VAF 7/18 reads (39%) | catalogued as rs775920384; called by muse, mutect2, varscan2
